CTSP case CTSP-ACY6 — CTSP-DLBCL1: CTSP Diffuse Large B-Cell Lymphoma (DLBCL) CALGB 50303
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3abe9621-e76c-4e23-95c4-df7224e537c2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Dead; Days to death: 1,350 days (3.7 years); Year of death: 2009; Cause of death: Cancer Related.

Diagnoses (1)
1. Diffuse large B-cell lymphoma, NOS: ICD-O-3 morphology code: 9680/3; Age at diagnosis: 60.4 years (22,073 days); Method of diagnosis: Biopsy; Ann Arbor pathologic stage: Stage II; Days to last follow up: 1,350 days (3.7 years); Best overall response: Complete Response; Ann Arbor extranodal involvement: Yes; International Prognostic Index (IPI): Low Risk.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 125 kg; Height: 180 cm; BMI: 38.6.

Biospecimens (1 sample)
- Sample DLBCL11285-sample: Sample type: Tumor; Tissue type: Tumor.
